Somatic mutation profile of tumor specimen C3N-01997-03 (aliquot CPT0138900010_1) from CPTAC case C3N-01997, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.4 years (23,169 days).
Specimen C3N-01997-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 861bcb30-69fa-4941-bcf1-f842e0cb1f80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01997-71 (Blood Derived Normal), aliquot CPT0138920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fd2958e-a5ce-4b08-b8c0-9d4d3c1342fd

The open-access MAF lists 42 somatic variants for this specimen: 24 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 12, Intron 3, Nonsense Mutation 2, 5'Flank 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 38/602 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 37/440 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.245); catalogued as rs587782197, COSV52676080, COSV52724970, COSV52728973; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- ADGRB2 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57079678; called by muse, mutect2
- CEP19 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1356324447; called by muse, mutect2
- FGF10 | c.530A>T p.Y177F | Missense Mutation (SNP) | VAF 25/700 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1453394033, COSV99240857; called by muse, mutect2
- KIF20B | c.796A>T p.S266C | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.518); catalogued as COSV53303965; called by muse, mutect2
- LGALS4 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs577868923; called by muse, mutect2
- LPCAT2 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 17/252 reads (7%) | catalogued as rs1360979777; called by muse, mutect2
- PER1 | c.2506C>T p.R836* | Nonsense Mutation (SNP) | VAF 14/218 reads (6%) | catalogued as rs1229815436; called by muse, mutect2
- PPP1R3A | c.3069A>C p.E1023D | Missense Mutation (SNP) | VAF 31/754 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.318); catalogued as COSV52893421; called by muse, mutect2
- PRSS16 | c.1274C>T p.T425M | Missense Mutation (SNP) | VAF 33/442 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756472444; called by muse, mutect2
- TTN | c.66634G>A p.D22212N (on ENST00000591111; = p.D14788N on NM_003319.4) | Missense Mutation (SNP) | VAF 26/184 reads (14%) | PolyPhen probably damaging (0.998); catalogued as rs1387991752; called by muse, mutect2, varscan2
- ZNF813 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 48/632 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs764637390, COSV67175591; called by muse, mutect2
- AKAP12 | c.1975G>C p.G659R | Missense Mutation (SNP) | VAF 16/391 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.066); called by muse, mutect2
- DCAF12L2 | c.1157G>T p.R386M | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.647); called by muse, mutect2
- ERCC3 | c.812A>T p.E271V | Missense Mutation (SNP) | VAF 20/501 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- KIF26B | c.5581C>T p.H1861Y | Missense Mutation (SNP) | VAF 25/700 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2
- LRP12 | c.1654T>A p.L552M | Missense Mutation (SNP) | VAF 10/330 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MLNR | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- PDE11A | c.2033C>G p.A678G | Missense Mutation (SNP) | VAF 63/944 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); called by muse, mutect2
- SKIDA1 | c.1639A>G p.N547D | Missense Mutation (SNP) | VAF 17/376 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2
- SS18 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 33/709 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- TBCB | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2
- ZBTB39 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 40/528 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.03); called by muse, mutect2
- ALPK3 | c.3867C>G p.S1289= | Silent (SNP) | VAF 70/564 reads (12%) | catalogued as rs188837127, COSV51936632; called by muse, mutect2, varscan2
- GRM1 | c.2346C>T p.N782= | Silent (SNP) | VAF 120/1139 reads (11%) | catalogued as rs145874853; ClinVar: likely benign; called by muse, mutect2, varscan2
- INHBB | c.135C>A p.P45= | Silent (SNP) | VAF 13/130 reads (10%) | called by mutect2, varscan2
- KRT82 | c.990C>T p.R330= | Silent (SNP) | VAF 26/456 reads (6%) | catalogued as rs1291756887; called by muse, mutect2
- LRP4 | c.4974T>A p.A1658= | Silent (SNP) | VAF 94/1074 reads (9%) | called by muse, mutect2
- MED13 | c.111C>G p.G37= | Silent (SNP) | VAF 23/260 reads (9%) | catalogued as rs746555652; called by muse, mutect2
- MYO18B | c.7101T>C p.S2367= | Silent (SNP) | VAF 22/442 reads (5%) | called by muse, mutect2
- NOS3 | c.2076G>A p.E692= | Silent (SNP) | VAF 27/344 reads (8%) | catalogued as rs778063544; called by muse, mutect2
- RAD54B | c.675G>A p.R225= | Silent (SNP) | VAF 36/659 reads (5%) | called by muse, mutect2
- RP1 | c.5679C>A p.G1893= | Silent (SNP) | VAF 18/442 reads (4%) | called by muse, mutect2
- ZNF521 | c.3111C>A p.I1037= | Silent (SNP) | VAF 131/541 reads (24%) | catalogued as COSV100833290; called by muse, mutect2, varscan2
- ZXDB | c.1059G>T p.A353= | Silent (SNP) | VAF 22/224 reads (10%) | catalogued as COSV66493385; called by muse, mutect2
- D2HGDH | c.854-813C>A | Intron (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- FADS1 | c.684+611A>T | Intron (SNP) | VAF 22/308 reads (7%) | called by muse, mutect2
- MIR4771-1 | chr2:87193509 T>C | 5'Flank (SNP) | VAF 16/463 reads (3%) | called by muse, mutect2
- MXD3 | c.506-17G>C | Intron (SNP) | VAF 26/340 reads (8%) | called by muse, mutect2
- SQSTM1 | c.*558C>A | 3'UTR (SNP) | VAF 22/236 reads (9%) | called by muse, mutect2
- WNK2 | chr9:93318436 G>A | 3'Flank (SNP) | VAF 32/474 reads (7%) | called by muse, mutect2
